CPTAC case C3N-02146 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0d46037d-04c5-484c-85cc-999f5991d538

Demographics
Sex at birth: female; Race: asian; Year of birth: 1948; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 69.7 years (25,450 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 4; Margin status: Indeterminate.

Other clinical attributes
- Weight: 59 kg; Height: 160 cm; BMI: 23.05.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02146-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 260 mg; Time between clamping and freezing: 20 minutes; Time between excision and freezing: 6 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02146-24: Section location: Lung; Percent tumor nuclei: 65; Percent necrosis: 15.
- Sample C3N-02146-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 250 mg; Time between clamping and freezing: 21 minutes; Time between excision and freezing: 5 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02146-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw.
